Surgical pathology report (de-identified scan), TCGA case TCGA-VD-A8KF, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-A8KF-01A (Primary Tumor).

[page 1 of 3]
Department of Pathology

Page 1 of 4

REPORT Tel:

Clinical Consultant & Location

Sex

Unit No

This Copy For:

SPECIMEN

Right eye.

CLINICAL DETAILS

Inferior ?---? detachment (variable thickness.

MACROSCOPIC DESCRIPTION

An intact right eye.

Dimensions: Axial 26mm; Horizontal 25mm; Vertical 26mm.

Cornea: Horizontal 12mm; Vertical: 12mm.

Optic nerve: Length 2mm; Diameter 5mm.

Pupil: Slightly eccentric towards inferior edge.

On trans-illumination, a shadow is seen in the inferior pole measuring 19 x 20mm.

Plane of section: Vertical.

Intraocular description:

On opening the eye, an amelanotic bilobated ciliochoroidal mass is present measuring 20mm at its larger base and 6.7mm in height. Tumour extends posteriorly to within 6mm of the optic disc.

Tumour size

LBD 20mm

Height 6.7mm

MICROSCOPY

Sections show a non-pigmented ciliochoroidal melanoma associated with exudative retinal detachment. The tumour consists of a mixed cell population in which the epithelioid cell component amounts up to 80%. Tumour cells express Melan-A and HSP 27 (score 2).

The number of mitosis is high, approximately 16/40 high power fields. The microvasculature of the melanoma is

ICD-O.3
Melanoma, epithelioid & spindle
cell mixed 8770/3
Site: Overlapping lesion of
eye & adnexa C69.8
JPD 1/17/14

Reported:

Pathologist:

Electronically Verified:

[page 2 of 3]
Department of Pathology

Page 2 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For: [REDACTED]

prominent, and closed loops are present in the planes of section. The lymphocytic infiltrate within the tumour is minimal. Tumour necrosis is not seen. There is focal tumour extension into the sclera. Optic nerve and vortex veins examined show no evidence of tumour involvement. There is no convincing evidence of ring pattern of spread. Tumour cells are not seen at the resection margins.

Elsewhere, the cornea shows no significant abnormality. The anterior chamber angles are open and the anterior chamber is deep. The iris appears uninvolved. The lens shows subcapsular degenerative changes. Retina overlying the tumour is slightly atrophic and Bruch's membrane appears intact in the sections examined.

DIAGNOSIS

Right enucleation - Ciliochoroidal melanoma of mixed cell type.

COMMENT

SPECIMEN	2= Eye
TUMOUR PRESENT	Yes
TUMOUR TYPE	1= Melanoma
CELL TYPE	3= Mixed
CT LOOPS	2= Closed loops
NECROSIS	No
PIGMENTATION	No
LYMPHOCYTIC INFILTRATION	No
MITOTIC FREQUENCY	16 /40 HPF
DIFFUSE MELANOMA	No
SPREAD	2= Intra-scleral
CLEARANCE	2= Adequate
HSP-27 POSITIVITY	2= 21-70%

Reported:

Pathologist:

Electronically Verified:

[page 3 of 3]
Department of Pathology

Page 3 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]		Sex [REDACTED]
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For: [REDACTED]

LARGE DIAMETER
THICKNESS

20 mm
6.7 mm

COMMENT

In the meantime, molecular genetic analysis of tumour DNA extracted from fresh uveal melanoma tissue was performed using the technique termed multiplex ligation-dependent probe amplification (MLPA). These investigations were performed in the

The kit P027 from [REDACTED] which examines for gains or losses in 31 loci on chromosomes 1, 3, 6 and 8, was used. The DNA concentration was measured using [REDACTED] and the quality assessed using multiplex-PCR prior to the MLPA reaction.

The DNA concentration was high and of good quality on assessment. The MLPA reaction was run at least twice on differing occasions, resulting in similar results.

The results of the sequence analysis of the MLPA products is printed on a separate report. In summary, sequence analysis demonstrated:

normal chromosome 1,
monosomy 3,
normal chromosome 6p
and gains of chromosome 8q.

These molecular data require correlation with the clinical and morphological data for metastatic risk assessment.

SUPPLEMENTARY REPORT

On request of the treating clinicians, BRAF testing of the primary tumour was performed. The sample was analysed for BRAF V600E gene mutation using the [REDACTED] BRAF RGQ PCR kit on a [REDACTED] PCR cycler.

The DNA was of sufficient quality: there was no V600E

Reported:

Pathologist:

Electronically Verified:

Qual/Sync/Version: Primary/Noted		✓

Source: NCI Genomic Data Commons file 3f3c02d4-33db-4dad-b433-f096be2d6258 (TCGA-VD-A8KF.9FFFF089-4156-4221-BCAC-20EEB748944C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).